Somatic mutation profile of tumor specimen TCGA-XM-AAZ3-01A (aliquot TCGA-XM-AAZ3-01A-11D-A423-09) from TCGA case TCGA-XM-AAZ3, project TCGA-THYM (Thymoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Thymoma, type AB, malignant; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 64.7 years (23,617 days).
Specimen TCGA-XM-AAZ3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcaf1a0f-24b4-4fd1-a2c7-4cbfae7cadc2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XM-AAZ3-12A (Buccal Cell Normal), aliquot TCGA-XM-AAZ3-12A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dc65f649-dee6-46ad-a900-f9e8ca6041ab

The open-access MAF lists 20 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 2, Splice Site 1, Nonsense Mutation 1, Translation Start Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GTF2I | c.1271T>A p.L424H (on ENST00000573035 / NM_032999.4; = p.L383H on NM_001518.5) | Missense Mutation (SNP) | VAF 157/376 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.963); catalogued as COSV60399097; called by muse, mutect2, varscan2
- HRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 25/45 reads (56%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs104894228, CM060018, COSV54236651, COSV54236730, COSV54241641; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- DNAH3 | c.3946G>A p.D1316N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs749568373, COSV54512690, COSV54541192; called by muse, mutect2, varscan2
- GRAMD1C | c.1789G>T p.E597* | Nonsense Mutation (SNP) | VAF 25/56 reads (45%) | catalogued as COSV100822965, COSV63982775; called by muse, mutect2, varscan2
- ITGAE | c.2030G>A p.R677Q | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.659); catalogued as rs745656428, COSV54000779; called by muse, mutect2, varscan2
- PLPPR4 | c.2113G>A p.V705I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as rs1428243344, COSV64567018; called by muse, mutect2, varscan2
- POLE3 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.147); catalogued as COSV55913509; called by muse, mutect2, varscan2
- RASAL2 | c.1439G>A p.R480H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs747149520, COSV100862436; called by muse, mutect2, varscan2
- AC131160.1 | c.692G>T p.S231I | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by mutect2, varscan2
- C1QTNF5 | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2
- CACNA1H | c.1036G>A p.V346M | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CARMIL1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- GNL3 | c.1606A>G p.I536V | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NR3C2 | c.2306T>G p.L769R | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SFT2D2 | c.51_63+19del p.X17_splice | Splice Site (DEL) | VAF 12/50 reads (24%) | called by pindel, varscan2
- SPTAN1 | c.4093G>A p.D1365N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- XKR4 | c.997G>C p.A333P | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- FAM160A2 | c.2592C>T p.L864= (on ENST00000449352 / NM_001098794.2; = p.L878= on NM_032127.4) | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV56410100; called by muse, mutect2, varscan2
- LRRC37A3 | c.4401G>A p.S1467= | Silent (SNP) | VAF 48/96 reads (50%) | catalogued as rs369882842; called by muse, mutect2, varscan2
- ZNF767P | n.195G>A | RNA (SNP) | VAF 19/35 reads (54%) | catalogued as rs778814236; called by muse, varscan2
